MMRF case MMRF_2198 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/388c43ed-a979-40b1-82e5-ddcdaab38a6b

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 55 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 55.2 years (20,175 days); ISS stage: III; Days to last known disease status: 897 days (2.5 years); Days to last follow up: 897 days (2.5 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 99 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 29 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 29 days; Days to treatment end: 99 days.
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 141 days; Days to treatment end: 225 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: Second line of therapy; Days to treatment start: 252 days; Days to treatment end: 252 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 365 days (1.0 years); Days to treatment end: 743 days (2.0 years).
   Treatment given: Therapeutic agents: Ixazomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 743 days (2.0 years); Days to treatment end: 897 days (2.5 years).
   Treatment given: Therapeutic agents: Daratumumab; Regimen or line of therapy: Third line of therapy; Days to treatment start: 943 days (2.6 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 0): M Protein 5.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 9.2 mg/dL; Immunoglobulin G 70.7 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 9.5 µg/mL; Lactate Dehydrogenase 2.42 µkat/L; Hemoglobin 5.02 mmol/L; Leukocytes 2.5 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 68 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.08 mmol/L; Albumin 33 g/L; Total Protein 10.6 g/dL; Glucose 5.72 mmol/L.
- Day 82 (ECOG 1): M Protein 1.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.9 mg/dL; Immunoglobulin G 13.2 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.201 g/L; Lactate Dehydrogenase 2.98 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 1.6 ×10⁹/L; Absolute Neutrophil 0.9 ×10⁹/L; Platelets 73 ×10⁹/L; Creatinine 92.8 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.23 mmol/L; Albumin 45 g/L; Total Protein 7.6 g/dL; Glucose 3.74 mmol/L.
- Day 169 (ECOG 1): M Protein 1.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1 mg/dL; Immunoglobulin G 11.9 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 2.8 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 109 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.13 mmol/L; Albumin 41 g/L; Total Protein 6.7 g/dL; Glucose 4.84 mmol/L.
- Day 274 (ECOG 1): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.8 mg/dL; Immunoglobulin G 7.78 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 3.63 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 85 ×10⁹/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.4 mmol/L; Albumin 40 g/L; Total Protein 7.6 g/dL; Glucose 6.27 mmol/L.
- Day 365 (ECOG 1): M Protein 0.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.9 mg/dL; Immunoglobulin G 15.4 g/L; Immunoglobulin A 0.823 g/L; Immunoglobulin M 0.304 g/L; Lactate Dehydrogenase 2.87 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 89 ×10⁹/L; Creatinine 98.1 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.4 mmol/L; Albumin 45 g/L; Total Protein 7.5 g/dL; Glucose 3.91 mmol/L.
- Day 463 (ECOG 1): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.6 mg/dL; Immunoglobulin G 12.2 g/L; Immunoglobulin A 0.427 g/L; Immunoglobulin M 0.429 g/L; Lactate Dehydrogenase 3.18 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 78 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.28 mmol/L; Albumin 47 g/L; Total Protein 7.5 g/dL; Glucose 4.29 mmol/L.
- Day 519 (ECOG 1): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.4 mg/dL; Immunoglobulin G 10.6 g/L; Immunoglobulin A 0.4 g/L; Immunoglobulin M 0.55 g/L; Lactate Dehydrogenase 3.13 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 88 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.43 mmol/L; Albumin 46 g/L; Total Protein 7.5 g/dL; Glucose 4.18 mmol/L.
- Day 631 (ECOG 1): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.3 mg/dL; Immunoglobulin G 11.1 g/L; Immunoglobulin A 0.53 g/L; Immunoglobulin M 0.63 g/L; Lactate Dehydrogenase 3.2 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 99 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.3 mmol/L; Albumin 45 g/L; Total Protein 7.1 g/dL; Glucose 4.73 mmol/L.
- Day 743 (ECOG 2): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.19 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.1 mg/dL; Immunoglobulin G 9.16 g/L; Immunoglobulin A 0.52 g/L; Immunoglobulin M 0.54 g/L; Lactate Dehydrogenase 2.97 µkat/L; Hemoglobin 8.56 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 81 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.35 mmol/L; Albumin 46 g/L; Total Protein 7.2 g/dL; Glucose 4.95 mmol/L.
- Day 841 (ECOG 1): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.17 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1 mg/dL; Immunoglobulin G 9.26 g/L; Immunoglobulin A 0.51 g/L; Immunoglobulin M 0.44 g/L; Lactate Dehydrogenase 3.27 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 80 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.35 mmol/L; Albumin 45 g/L; Total Protein 7.4 g/dL; Glucose 5.89 mmol/L.
- Day 897 (ECOG 1): M Protein 0.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.96 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1 mg/dL; Immunoglobulin G 11.2 g/L; Immunoglobulin A 0.5 g/L; Immunoglobulin M 0.28 g/L; Lactate Dehydrogenase 3.63 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 79 ×10⁹/L; Creatinine 91.1 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.28 mmol/L; Albumin 45 g/L; Total Protein 7.1 g/dL; Glucose 4.68 mmol/L.

Other clinical attributes
- Day 1: Weight: 111 kg; Height: 180 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2198_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_2198_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
